Somatic mutation profile of tumor specimen TCGA-B6-A0RT-01A (aliquot TCGA-B6-A0RT-01A-21D-A099-09) from TCGA case TCGA-B6-A0RT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 39.4 years (14,374 days).
Specimen TCGA-B6-A0RT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6784bd52-f5f9-4526-829f-f7c0361528da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RT-10A (Blood Derived Normal), aliquot TCGA-B6-A0RT-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18f764a8-e41a-4371-bf03-ca4d63055f4c

The open-access MAF lists 53 somatic variants for this specimen: 45 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 7, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 14/190 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2
- ALOX12B | c.2001G>T p.Q667H | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100047508; called by muse, mutect2
- ANO9 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV100241125; called by muse, mutect2
- C11orf87 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV59355961, COSV59358990; called by muse, mutect2
- C1S | c.1204C>G p.H402D | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100196708; called by muse, mutect2
- CACNA1E | c.4820T>G p.L1607R | Missense Mutation (SNP) | VAF 17/465 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100704317; called by muse, mutect2
- COL4A2 | c.2728G>C p.D910H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as COSV64624412; called by muse, mutect2
- EDARADD | c.575A>G p.E192G (on ENST00000334232 / NM_145861.4; = p.E182G on NM_080738.4) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV62060846; called by muse, mutect2
- EPC2 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.954); catalogued as COSV99309965; called by muse, mutect2
- EPHA7 | c.1441T>A p.Y481N | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65176896; called by muse, mutect2
- FAM219A | c.436G>C p.D146H (on ENST00000445726; = p.D129H on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99897145; called by muse, mutect2
- FATE1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV64848804; called by muse, mutect2, varscan2
- FBN3 | c.4665C>A p.N1555K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs1472445388, COSV54452600; called by muse, mutect2
- FNDC3B | c.3057A>T p.R1019S | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100394618; called by muse, mutect2
- FRYL | c.7770A>C p.E2590D | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99977619; called by muse, mutect2
- GJA5 | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV54782782; called by muse, mutect2, varscan2
- GNE | c.199C>G p.P67A (on ENST00000396594 / NM_001128227.3; = p.P36A on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV64951208; called by muse, mutect2
- H2AC1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 40/454 reads (9%) | catalogued as COSV51236692; called by muse, mutect2
- H2AP | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs781203861, COSV61910739; called by muse, mutect2
- HEPACAM2 | c.745G>C p.D249H (on ENST00000394468 / NM_001039372.4; = p.D237H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100506453, COSV100506641, COSV100506671; called by muse, mutect2
- HSPA12B | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.62); catalogued as rs199871927, COSV54765475, COSV99653821; called by muse, mutect2, varscan2
- KCNH6 | c.2062del p.A688Qfs*99 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | catalogued as COSV59006847; called by mutect2, pindel, varscan2
- LARGE2 | c.318T>G p.H106Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV57683944, COSV57684002; called by muse, mutect2, varscan2
- LRP2 | c.10210G>C p.D3404H | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV55539517; called by muse, mutect2
- MACO1 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV65474923; called by muse, mutect2, varscan2
- MAGEA8 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV54063575; called by muse, mutect2, varscan2
- MAGI1 | c.2583C>G p.I861M (on ENST00000402939 / NM_001033057.2; = p.I889M on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV58313079; called by muse, mutect2
- MICAL2 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99818024, COSV99818394; called by muse, mutect2
- MXRA5 | c.7880G>A p.R2627K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as rs764109761, COSV54222819; called by muse, mutect2, varscan2
- NLRP13 | c.1329C>G p.Y443* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV61619711, COSV61622587; called by muse, mutect2, varscan2
- NMBR | c.1161A>C p.E387D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV57800334; called by muse, mutect2
- NUP107 | c.2420A>G p.D807G | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs375498676; called by muse, mutect2
- OPN1LW | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 43/557 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV64049264; called by muse, mutect2
- PEAR1 | c.66C>A p.N22K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1371892874, COSV99442025; called by muse, mutect2
- PI4KA | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs762036318, COSV55403222; called by muse, mutect2
- PRPH2 | c.775A>T p.S259C | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV100028192; called by muse, mutect2
- RBM12 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV58289549; called by muse, mutect2
- RNF38 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV52396397; called by muse, mutect2
- SORT1 | c.1799A>C p.Y600S | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); catalogued as COSV99860977; called by muse, mutect2
- STAMBPL1 | c.975G>C p.M325I | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64222130; called by muse, mutect2
- TARBP1 | c.2872-1G>T p.X958_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV50178142; called by muse, mutect2, varscan2
- USP24 | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV99600501; called by muse, mutect2
- LRRC36 | c.2057_2070delinsATCC p.V686Dfs*7 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by pindel, varscan2*
- PTH2R | c.703G>C p.G235R | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF791 | c.67_85delinsTCTGCATC p.P23Sfs*27 | Frame Shift Del (DEL) | VAF 12/141 reads (9%) | called by muse*, pindel
- ASPN | c.1101T>G p.V367= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV65015800; called by muse, mutect2
- GPR173 | c.567C>T p.F189= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV60233145; called by muse, mutect2, varscan2
- KCNH5 | c.786C>T p.I262= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV59761198, COSV59768519; called by muse, mutect2
- KRT23 | c.585G>A p.E195= | Silent (SNP) | VAF 16/312 reads (5%) | catalogued as COSV99266306; called by muse, mutect2
- PALB2 | c.2595A>T p.S865= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV55161989; called by muse, mutect2
- SUSD2 | c.717C>A p.P239= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV64202663; called by muse, mutect2
- UNC45B | c.1887T>A p.G629= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as COSV52091840; called by muse, mutect2
- ATP11AUN | n.775C>T | RNA (SNP) | VAF 9/49 reads (18%) | catalogued as rs369042046; called by muse, mutect2, varscan2
